Somatic mutation profile of tumor specimen C3L-05229-01 (aliquot CPT0272490009) from CPTAC case C3L-05229, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 82.3 years (30,074 days).
Specimen C3L-05229-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e225a11-03b3-4d82-a031-9a8aafed4170.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05229-31 (Blood Derived Normal), aliquot CPT0272570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a1f2d29-8f99-4446-8542-1183ad8a8948

The open-access MAF lists 1,164 somatic variants for this specimen: 700 protein-altering or splice-affecting, 410 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 635, Silent 410, Nonsense Mutation 46, Intron 33, Splice Region 8, 5'Flank 5, 3'UTR 5, Frame Shift Del 5, RNA 5, Splice Site 3, 5'UTR 3, 3'Flank 3.

Variants (750 of 1,164; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYL2 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 77/369 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397516406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RIT1 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 177/314 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs483352822, CM136419, CM148229, COSV64170809, COSV64170843, COSV64170960; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- RSRC1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 66/268 reads (25%) | catalogued as rs1183090232, COSV55823761; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 100/278 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP63 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 86/318 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen possibly damaging (0.664); catalogued as rs147148566, COSV53202265, COSV53220854; called by muse, mutect2, varscan2
- ABCB11 | c.2471G>A p.G824E | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1559191495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.3895C>T p.P1299S | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53979058; called by muse, mutect2, varscan2
- ACSM4 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 81/300 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs368493928; called by muse, mutect2, varscan2
- ACVR1C | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV54646170; called by muse, mutect2, varscan2
- ADAMTS20 | c.2599C>T p.Q867* | Nonsense Mutation (SNP) | VAF 69/234 reads (29%) | catalogued as rs371385651; called by muse, mutect2, varscan2
- ADAMTS9 | c.4502G>A p.W1501* | Nonsense Mutation (SNP) | VAF 87/318 reads (27%) | catalogued as COSV55780620; called by muse, mutect2, varscan2
- ADAMTSL2 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 96/390 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754545792; called by muse, mutect2, varscan2
- ADARB2 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 83/403 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67232977; called by muse, mutect2, varscan2
- AKAP11 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 87/294 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1317540430, COSV99213763; called by muse, mutect2, varscan2
- AKAP14 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 90/163 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs978267657, COSV57629200; called by muse, mutect2, varscan2
- AL645922.1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 389/950 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.77); catalogued as rs1277611780, COSV54962135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV66583826; called by muse, mutect2
- ANK1 | c.4993G>A p.D1665N | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV55881094; called by muse, mutect2, varscan2
- ANKRD9 | c.716C>A p.T239N | Missense Mutation (SNP) | VAF 34/626 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV54601948; called by muse, mutect2
- ANO4 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 111/565 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54586601; called by muse, mutect2, varscan2
- ANXA11 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 115/516 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1424872965; called by muse, mutect2, varscan2
- ANXA3 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 91/378 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV53715481; called by muse, mutect2, varscan2
- APOB | c.5247G>A p.M1749I | Missense Mutation (SNP) | VAF 120/443 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV51925904; called by muse, mutect2, varscan2
- ARFGEF3 | c.5108G>A p.G1703E | Missense Mutation (SNP) | VAF 79/371 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1461088358; called by muse, mutect2, varscan2
- ARHGAP28 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 96/452 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as rs534903406; called by muse, mutect2, varscan2
- ARHGEF17 | c.5978C>T p.P1993L | Missense Mutation (SNP) | VAF 77/313 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as rs765884623; called by muse, mutect2, varscan2
- ARID1B | c.6325C>T p.R2109C | Missense Mutation (SNP) | VAF 105/575 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51684555; called by muse, mutect2, varscan2
- ARMH4 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 99/425 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs774365121; called by muse, mutect2, varscan2
- ART4 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 81/392 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1201103453; called by muse, mutect2
- ART5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 116/505 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.088); catalogued as rs144276806; called by muse, mutect2, varscan2
- ASTN1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866639170, COSV56061286; called by muse, mutect2, varscan2
- ATRX | c.5353C>T p.Q1785* | Nonsense Mutation (SNP) | VAF 101/181 reads (56%) | catalogued as COSV64882597, COSV64885586; called by muse, mutect2, varscan2
- BAG6 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 186/1023 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as rs751257971; called by muse, mutect2, varscan2
- BEST3 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV56994147; called by muse, mutect2, varscan2
- BLK | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.06); catalogued as rs765924109, COSV99377551; called by muse, mutect2, varscan2
- BRD2 | c.2291C>T p.S764F | Missense Mutation (SNP) | VAF 151/385 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs200164898; called by muse, mutect2, varscan2
- BRD8 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 209/523 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as rs747706827; called by muse, mutect2, varscan2
- BRDT | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 89/360 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62863553; called by muse, mutect2, varscan2
- BRIP1 | c.2963C>T p.S988F | Missense Mutation (SNP) | VAF 94/362 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.99); catalogued as rs758032378, COSV51995432, COSV52003653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTBD7 | c.2317C>T p.H773Y | Missense Mutation (SNP) | VAF 232/464 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs1385183261, COSV58285332; called by muse, varscan2
- C5 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 100/445 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1402957355, COSV56324454; called by muse, mutect2, varscan2
- C5AR1 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 123/306 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as rs764230867; called by muse, mutect2, varscan2
- C9 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 101/559 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs774497549; called by muse, mutect2, varscan2
- CAGE1 | c.1969A>C p.S657R (on ENST00000512086; = p.S521R on NM_205864.3) | Missense Mutation (SNP) | VAF 114/325 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.316); catalogued as rs376464144; called by muse, mutect2
- CATSPER4 | c.1393C>T p.L465F | Missense Mutation (SNP) | VAF 95/390 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.296); catalogued as rs1270067512, COSV58793521; called by muse, mutect2, varscan2
- CATSPERB | c.2804C>T p.S935L | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1356348990, COSV56429545; called by muse, mutect2, varscan2
- CATSPERD | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 96/384 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs745670557, COSV58465097; called by muse, mutect2, varscan2
- CCDC33 | c.589A>C p.N197H | Missense Mutation (SNP) | VAF 143/372 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as COSV100351494; called by muse, mutect2, varscan2
- CCDC39 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 100/517 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99869036, COSV99870314; called by muse, mutect2, varscan2
- CD101 | c.2254C>T p.H752Y | Missense Mutation (SNP) | VAF 104/445 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV56721547; called by muse, mutect2, varscan2
- CD163 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 138/508 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373039092; called by muse, mutect2, varscan2
- CD2 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 74/387 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65643353; called by muse, mutect2, varscan2
- CDH23 | c.6541G>A p.V2181M | Missense Mutation (SNP) | VAF 89/289 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV56458160; called by muse, mutect2, varscan2
- CDH9 | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 272/505 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV50452461; called by muse, mutect2, varscan2
- CDKN2A | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 35/488 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.087); catalogued as rs1060501275, COSV58712901; ClinVar: uncertain significance; called by muse, mutect2
- CELSR3 | c.5509C>T p.L1837F | Missense Mutation (SNP) | VAF 130/544 reads (24%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.532); catalogued as COSV50847442; called by muse, mutect2, varscan2
- CFAP69 | c.1048C>T p.L350F | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV60188432; called by muse, mutect2, varscan2
- CFHR3 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as rs1460615140, COSV66401464; called by muse, mutect2, varscan2
- CHAT | c.2233G>A p.G745R | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.296); catalogued as rs1307042855; called by muse, mutect2, varscan2
- CHL1 | c.2225G>A p.G742E (on ENST00000397491 / NM_001253387.1; = p.G758E on NM_006614.4) | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56587788; called by muse, mutect2, varscan2
- CHRNA4 | c.300G>A p.W100* | Nonsense Mutation (SNP) | VAF 84/290 reads (29%) | catalogued as COSV64717492; called by muse, mutect2, varscan2
- CLASP2 | c.4372C>T p.R1458W (on ENST00000359576; = p.R1457W on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/314 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56279532; called by muse, mutect2, varscan2
- CNTNAP2 | c.3946C>T p.P1316S | Missense Mutation (SNP) | VAF 230/526 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as COSV62265792; called by muse, mutect2, varscan2
- COL14A1 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 103/422 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as rs1395586117; called by muse, mutect2, varscan2
- COL14A1 | c.3853G>A p.D1285N | Missense Mutation (SNP) | VAF 66/279 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs770207407, COSV52847595; called by muse, mutect2, varscan2
- COL4A4 | c.2749C>T p.P917S | Missense Mutation (SNP) | VAF 103/399 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237546505, COSV61630230; called by muse, mutect2, varscan2
- COL6A6 | c.4384G>A p.E1462K | Missense Mutation (SNP) | VAF 99/490 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV62034379; called by muse, mutect2, varscan2
- COMP | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 143/560 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs1404966013; called by muse, mutect2, varscan2
- COX16 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs148696056; called by muse, mutect2, varscan2
- COX4I2 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 87/327 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV101064212; called by muse, mutect2, varscan2
- CPAMD8 | c.717C>G p.S239R (on ENST00000651564; = p.S192R on NM_015692.5) | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV52230599; called by muse, mutect2, varscan2
- CSMD1 | c.10579G>A p.E3527K (on ENST00000520002; = p.E3526K on NM_033225.6) | Missense Mutation (SNP) | VAF 115/309 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59287663, COSV59312285; called by muse, mutect2, varscan2
- CSMD1 | c.3193G>A p.G1065R (on ENST00000520002; = p.G1064R on NM_033225.6) | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1393229621; called by muse, mutect2, varscan2
- CSMD2 | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 100/464 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53906210; called by muse, varscan2
- CTAGE1 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1460375878; called by muse, mutect2, varscan2
- CUL9 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 201/534 reads (38%) | catalogued as rs145732465; called by muse, mutect2, varscan2
- CXXC5 | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 220/554 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.785); catalogued as COSV56795320; called by muse, mutect2, varscan2
- CYP2C9 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 135/406 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV53246817; called by muse, mutect2, varscan2
- CYP4F11 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 86/337 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV56126831; called by muse, varscan2
- CYP4F8 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 117/445 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs749764848; called by muse, mutect2, varscan2
- CYP4F8 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs558107890, COSV57853829; called by muse, mutect2, varscan2
- DCDC2C | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as COSV67688408; called by muse, mutect2, varscan2
- DDR2 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 250/467 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1268023328; called by muse, mutect2, varscan2
- DGKG | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 103/438 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99402743; called by muse, mutect2, varscan2
- DGKH | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 105/334 reads (31%) | catalogued as rs9566925, COSV54931621; called by muse, mutect2, varscan2
- DMRT3 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 130/369 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.565); catalogued as rs1175833519, COSV51904296; called by muse, mutect2, varscan2
- DMXL1 | c.4084G>A p.E1362K | Missense Mutation (SNP) | VAF 88/483 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs1348962990; called by muse, mutect2, varscan2
- DMXL2 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 110/302 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143486672, COSV51843689; called by muse, mutect2, varscan2
- DNAH11 | c.8534G>A p.R2845Q | Missense Mutation (SNP) | VAF 111/367 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs372633683, COSV100179874; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH17 | c.10966G>A p.E3656K | Missense Mutation (SNP) | VAF 111/473 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.182); catalogued as COSV67750530; called by muse, mutect2, varscan2
- DNAH8 | c.12947C>T p.S4316L | Missense Mutation (SNP) | VAF 341/657 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs765766734, COSV59443932; called by muse, mutect2, varscan2
- DNAH9 | c.8830C>T p.R2944W | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1314819352, COSV52360445; called by muse, mutect2, varscan2
- DOCK3 | c.4184C>T p.P1395L | Missense Mutation (SNP) | VAF 107/483 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1474532565; called by muse, mutect2, varscan2
- DPY19L2 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs748677303, COSV61042189; called by muse, mutect2, varscan2
- DSG1 | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57138216; called by muse, mutect2, varscan2
- DSG4 | c.2747C>T p.P916L | Missense Mutation (SNP) | VAF 62/343 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs866991926; called by muse, mutect2, varscan2
- DVL3 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 71/432 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs1056924700; called by muse, mutect2, varscan2
- DYRK4 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 98/354 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs759186486; called by muse, mutect2, varscan2
- E2F4 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 124/357 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58878376; called by muse, mutect2, varscan2
- EFEMP2 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 155/752 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.342); catalogued as COSV57259704; called by muse, mutect2
- ELAPOR2 | c.2072A>G p.N691S (on ENST00000450689 / NM_001142749.3; = p.N524S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/371 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV51887168; called by muse, mutect2, varscan2
- ELOA2 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as rs149432716; called by muse, mutect2, varscan2
- ELP2 | c.1953C>T p.F651= | Splice Region (SNP) | VAF 66/243 reads (27%) | catalogued as rs200848954, COSV60853619; called by muse, mutect2, varscan2
- EPN2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59060580; called by muse, mutect2, varscan2
- ERICH3 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 137/490 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV58598628; called by muse, mutect2, varscan2
- EXOC4 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 157/483 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV54100286; called by muse, mutect2, varscan2
- EYS | c.6613C>T p.L2205F | Missense Mutation (SNP) | VAF 71/330 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1290357542, COSV101008493, COSV101011693; called by muse, mutect2, varscan2
- FAM160A1 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 129/458 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV70706527; called by muse, mutect2, varscan2
- FAM20C | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1232400875; called by muse, mutect2, varscan2
- FAM47A | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 135/273 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs752456861, COSV60498629; called by muse, mutect2, varscan2
- FAT1 | c.9386C>T p.P3129L | Missense Mutation (SNP) | VAF 118/506 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs1208705070, COSV101499761; called by muse, mutect2
- FAT1 | c.9385C>T p.P3129S | Missense Mutation (SNP) | VAF 118/508 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.424); catalogued as COSV71673549; called by muse, mutect2
- FAT3 | c.4637G>A p.R1546Q | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs746923546, COSV53086601, COSV53187272; called by muse, mutect2, varscan2
- FAT3 | c.7681G>A p.E2561K | Missense Mutation (SNP) | VAF 100/383 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53114232; called by muse, mutect2, varscan2
- FAT4 | c.11462G>A p.R3821Q | Missense Mutation (SNP) | VAF 100/379 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as rs142857910; called by muse, mutect2, varscan2
- FBLN2 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 134/543 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs769428931; called by muse, mutect2, varscan2
- FBN2 | c.1835G>A p.G612E | Missense Mutation (SNP) | VAF 71/343 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1276413246, COSV52544692; called by muse, mutect2, varscan2
- FHAD1 | c.2798C>T p.A933V | Missense Mutation (SNP) | VAF 107/456 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1290010039; called by muse, mutect2
- FLT1 | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV56744445; called by muse, mutect2, varscan2
- FMN2 | c.2921G>A p.G974E | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.409); catalogued as rs768840625, COSV60421408; called by muse, varscan2
- FTMT | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 244/569 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV58420682; called by muse, mutect2, varscan2
- FUS | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 147/638 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.425); catalogued as rs769882255, COSV54218676; called by muse, mutect2, varscan2
- FZD10 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 132/506 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57473522; called by muse, mutect2, varscan2
- GABRA2 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 76/289 reads (26%) | catalogued as rs748381199; called by muse, mutect2, varscan2
- GAL3ST1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 165/550 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1448739050; called by muse, mutect2, varscan2
- GALNT7 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 96/359 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99397861; called by muse, mutect2, varscan2
- GIT2 | c.2226C>G p.I742M (on ENST00000355312 / NM_057169.5; = p.I664M on NM_014776.5) | Missense Mutation (SNP) | VAF 110/375 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58078301; called by muse, mutect2, varscan2
- GNAI2 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 82/294 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as COSV99807055; called by muse, mutect2, varscan2
- GNB3 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 108/480 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51833364; called by muse, mutect2, varscan2
- GPATCH8 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 102/436 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV59193670; called by muse, mutect2, varscan2
- GPC6 | c.1268G>A p.W423* | Nonsense Mutation (SNP) | VAF 73/265 reads (28%) | catalogued as COSV65504846; called by muse, mutect2, varscan2
- GPC6 | c.1269G>A p.W423* | Nonsense Mutation (SNP) | VAF 73/261 reads (28%) | catalogued as COSV65533220; called by muse, mutect2, varscan2
- GPR137 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 142/525 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV57401117; called by muse, mutect2, varscan2
- GPR152 | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 98/521 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183537840; called by muse, varscan2
- GPR152 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 112/563 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369375444; called by muse, mutect2, varscan2
- GUCY2F | c.3134G>A p.G1045E | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs769316117; called by muse, mutect2, varscan2
- GXYLT1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.513); catalogued as rs75740340, COSV99789204; called by muse, mutect2, varscan2
- HDAC9 | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67770898; called by muse, mutect2, varscan2
- HDGFL3 | c.191C>A p.P64Q | Missense Mutation (SNP) | VAF 304/594 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55206509; called by muse, varscan2
- HRG | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 152/346 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs138389406; called by muse, mutect2, varscan2
- HSD17B3 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 89/400 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV64556183; called by muse, mutect2, varscan2
- HSD3B2 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 73/310 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as CM152934; called by muse, mutect2, varscan2
- HSPG2 | c.11015C>T p.S3672F | Missense Mutation (SNP) | VAF 64/317 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65933925; called by muse, mutect2, varscan2
- ICOS | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 93/343 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs769976991; called by muse, mutect2, varscan2
- IGFBP6 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 105/376 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV56857336; called by muse, mutect2, varscan2
- IGSF1 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 97/156 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as rs1161560765; called by muse, mutect2, varscan2
- IL5RA | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 108/437 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.011); catalogued as rs1181321792, COSV56526453; called by muse, mutect2, varscan2
- INPP5J | c.1502C>T p.S501L (on ENST00000331075 / NM_001284285.2; = p.S133L on NM_001002837.2) | Missense Mutation (SNP) | VAF 77/301 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs762702897, COSV58512130; called by muse, mutect2, varscan2
- ITGA7 | c.940G>A p.G314R (on ENST00000555728; = p.G270R on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs776086093; called by muse, mutect2, varscan2
- ITGB8 | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.04); catalogued as COSV56011968, COSV99752091; called by muse, mutect2, varscan2
- ITIH5 | c.1961G>A p.G654E | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.519); catalogued as rs1194534685; called by muse, mutect2, varscan2
- JUNB | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 118/444 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1206864789; called by muse, mutect2, varscan2
- KAT6B | c.3505A>G p.M1169V | Missense Mutation (SNP) | VAF 136/545 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.448); catalogued as rs1281390253; called by muse, mutect2, varscan2
- KCNH1 | c.1078C>T p.R360C (on ENST00000271751 / NM_172362.3; = p.R333C on NM_002238.4) | Missense Mutation (SNP) | VAF 108/322 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55084722, COSV55099309; called by muse, mutect2, varscan2
- KCNJ12 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 118/850 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as rs781837859, COSV100055143; called by muse, mutect2
- KIAA0930 | c.937C>T p.R313W (on ENST00000336156 / NM_001009880.2; = p.R318W on NM_015264.2) | Missense Mutation (SNP) | VAF 134/576 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs761596276; called by muse, mutect2, varscan2
- KIF26B | c.2591C>T p.T864I | Missense Mutation (SNP) | VAF 219/589 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868553515; called by muse, mutect2, varscan2
- KIF4B | c.3202G>A p.D1068N | Missense Mutation (SNP) | VAF 216/595 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV70528946, COSV70531999; called by muse, mutect2, varscan2
- KIR2DL1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 84/564 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs755106117; called by muse, varscan2
- KMT2C | c.2906G>A p.G969E | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100072749; called by muse, mutect2
- KPNA1 | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 69/356 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60267794; called by muse, mutect2, varscan2
- KRT6B | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 95/666 reads (14%) | catalogued as COSV52884264; called by muse, mutect2, varscan2
- KRT73 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1276797311, COSV59840933; called by muse, mutect2, varscan2
- LAMA2 | c.4493C>T p.P1498L | Missense Mutation (SNP) | VAF 120/407 reads (29%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.998); catalogued as rs780597365; called by muse, mutect2, varscan2
- LILRA1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs747596999, COSV99252080; called by muse, mutect2, varscan2
- LILRB5 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV60256554; called by muse, mutect2, varscan2
- LPIN2 | c.1938C>T p.I646= | Splice Region (SNP) | VAF 74/439 reads (17%) | catalogued as rs766117626, COSV99859095; called by muse, mutect2, varscan2
- LRG1 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 120/475 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199538618; called by muse, mutect2, varscan2
- LRP1B | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs868652515, COSV67213914; called by muse, mutect2, varscan2
- LRP2 | c.11926G>A p.E3976K | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as rs779749899, COSV55563324, COSV55565845; called by muse, mutect2, varscan2
- LRP2 | c.8830C>T p.Q2944* | Nonsense Mutation (SNP) | VAF 71/278 reads (26%) | catalogued as rs956340396; called by muse, mutect2, varscan2
- LRRC18 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 132/349 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs200643784; called by muse, mutect2, varscan2
- LRRC43 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 130/526 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1203956985; called by muse, mutect2, varscan2
- LTBR | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 115/514 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs771908386; called by muse, mutect2, varscan2
- MAGEC3 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 145/259 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV53578731; called by muse, mutect2, varscan2
- MALRD1 | c.1562C>T p.S521L | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.154); catalogued as rs533846440; called by muse, mutect2, varscan2
- MAMDC4 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 148/497 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.025); catalogued as rs745317494; called by muse, mutect2, varscan2
- MAN2B1 | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 112/433 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs376856949, COSV55475007; called by muse, mutect2, varscan2
- MAP3K9 | c.3284C>T p.P1095L (on ENST00000554752 / NM_001284230.1; = p.P1109L on NM_033141.4) | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1322590535; called by muse, mutect2, varscan2
- MAST2 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 132/448 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs1020007935, COSV100787977; called by muse, mutect2, varscan2
- MAST2 | c.4459G>A p.E1487K | Missense Mutation (SNP) | VAF 99/490 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.427); catalogued as rs774220165, COSV100787931; called by muse, mutect2, varscan2
- MCU | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 72/288 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV64064566; called by muse, mutect2, varscan2
- MEP1B | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.42); catalogued as rs567194983; called by muse, mutect2, varscan2
- MEX3D | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 224/840 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs1317566677; called by muse, mutect2, varscan2
- MFAP1 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 136/332 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as rs1209026918; called by muse, mutect2, varscan2
- MICAL3 | c.5111C>T p.S1704F | Missense Mutation (SNP) | VAF 136/526 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101490794, COSV71588764; called by muse, mutect2, varscan2
- MKS1 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs201237547, COSV58302832; called by muse, mutect2, varscan2
- MROH2B | c.1709G>A p.W570* | Nonsense Mutation (SNP) | VAF 120/316 reads (38%) | catalogued as COSV101270593; called by muse, mutect2, varscan2
- MSH3 | c.2767C>T p.P923S | Missense Mutation (SNP) | VAF 99/483 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs763008024; called by muse, mutect2, varscan2
- MTOR | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 98/366 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1278746815, COSV63876016; called by muse, mutect2, varscan2
- MUC12 | c.15706G>A p.D5236N (on ENST00000379442; = p.D5093N on NM_001164462.1) | Missense Mutation (SNP) | VAF 97/371 reads (26%) | SIFT deleterious (0.02); catalogued as rs769389695; called by muse, mutect2, varscan2
- MUC16 | c.38275G>A p.E12759K | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as rs1162696216, COSV67476294; called by muse, mutect2, varscan2
- MUC16 | c.27917G>A p.S9306N | Missense Mutation (SNP) | VAF 139/481 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs1417001381, COSV67444084; called by muse, mutect2, varscan2
- MUC16 | c.17447G>A p.R5816K | Missense Mutation (SNP) | VAF 101/368 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.019); catalogued as COSV67476432; called by muse, mutect2, varscan2
- MUC16 | c.16307C>T p.S5436L | Missense Mutation (SNP) | VAF 114/455 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.281); catalogued as COSV101200983; called by muse, mutect2, varscan2
- MUC16 | c.12455C>T p.S4152F | Missense Mutation (SNP) | VAF 115/462 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.148); catalogued as rs1365396674, COSV67468120; called by muse, mutect2, varscan2
- MUC17 | c.11372G>A p.G3791D | Missense Mutation (SNP) | VAF 118/438 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as rs752165834; called by muse, varscan2
- MUSK | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as COSV51886784; called by muse, mutect2, varscan2
- MYH7 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 128/508 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.778); catalogued as rs730880879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs397516267, CM1410887, COSV62520552, COSV62523895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1A | c.2824G>A p.G942R | Missense Mutation (SNP) | VAF 107/456 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.334); catalogued as COSV55653227; called by muse, mutect2, varscan2
- MYO3A | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 97/358 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762040109; called by muse, mutect2, varscan2
- MYO5B | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 91/352 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762183636, COSV53214965; called by muse, mutect2, varscan2
- MYO7A | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68684526, COSV68686937; called by muse, mutect2, varscan2
- MYO7B | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 82/337 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs770751834, COSV67344446; called by muse, mutect2, varscan2
- MYOM2 | c.4144G>A p.D1382N | Missense Mutation (SNP) | VAF 178/458 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs769907128, COSV50716965; called by muse, mutect2, varscan2
- NEB | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV51458786; called by muse, mutect2, varscan2
- NECAB3 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 124/449 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs1422656172; called by muse, mutect2, varscan2
- NEK10 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 42/249 reads (17%) | catalogued as rs776635841, COSV58281225; called by muse, mutect2, varscan2
- NF1 | c.5464C>T p.Q1822* (on ENST00000358273 / NM_001042492.3; = p.Q1801* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 128/407 reads (31%) | catalogued as CM062903, COSV62196355; called by muse, mutect2, varscan2
- NFKBIE | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 116/642 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV51487728; called by muse, mutect2, varscan2
- NKAIN2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 107/287 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.419); catalogued as rs767024716, COSV63677421; called by muse, mutect2, varscan2
- NLRP11 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 95/249 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.082); catalogued as rs937856777, COSV64088669; called by muse, mutect2, varscan2
- NLRP3 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 146/390 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100276155, COSV60220473; called by muse, mutect2, varscan2
- NOSTRIN | c.604G>A p.E202K (on ENST00000317647 / NM_001039724.4; = p.E124K on NM_052946.3) | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs937627241; called by muse, mutect2, varscan2
- NOX4 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.865); catalogued as rs905405152, COSV54448648; called by muse, mutect2, varscan2
- NPAP1 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 107/312 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs780887163; called by muse, mutect2, varscan2
- NR1D1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 110/442 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.099); catalogued as rs548379714; called by mutect2, varscan2
- NTPCR | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 96/276 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64053065; called by muse, mutect2, varscan2
- NUDC | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 184/677 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs756553114; called by muse, mutect2, varscan2
- NUP210 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 100/399 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs943811331, COSV54408622, COSV54412835; called by muse, mutect2, varscan2
- NXNL2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 146/569 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.411); catalogued as rs748931914, COSV65474242; called by muse, mutect2, varscan2
- NYNRIN | c.2573C>T p.S858L | Missense Mutation (SNP) | VAF 109/407 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); catalogued as rs547499850; called by muse, mutect2, varscan2
- OOSP2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140171460, COSV53928347, COSV99613480; called by muse, mutect2, varscan2
- OR10K2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 123/452 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs111878656, COSV59220924; called by muse, mutect2, varscan2
- OR10Q1 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 90/376 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104414483; called by muse, mutect2, varscan2
- OR11H1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 91/803 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99421539; called by muse, mutect2, varscan2
- OR2AG2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 88/366 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV58454619; called by muse, mutect2, varscan2
- OR2M5 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 127/362 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100822877; called by muse, mutect2, varscan2
- OR2T34 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 109/320 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200153945, COSV60900029; called by muse, varscan2
- OR4B1 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 112/446 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs867887191; called by muse, mutect2, varscan2
- OR4K13 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 95/329 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59859697; called by muse, mutect2, varscan2
- OR4K5 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 84/548 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV60003041; called by muse, mutect2, varscan2
- OR4M1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 155/888 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100271246; called by muse, mutect2, varscan2
- OR52D1 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 154/485 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as rs763956444; called by muse, mutect2, varscan2
- OR52E8 | c.50C>A p.S17* | Nonsense Mutation (SNP) | VAF 98/384 reads (26%) | catalogued as COSV66210521; called by muse, mutect2, varscan2
- OR6C65 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 80/384 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV101110192; called by muse, mutect2, varscan2
- OR8K3 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 90/363 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs200418517, COSV57130852; called by muse, mutect2, varscan2
- OTOF | c.3826C>T p.P1276S (on ENST00000272371 / NM_194248.3; = p.P509S on NM_004802.4) | Missense Mutation (SNP) | VAF 96/369 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs780946755; called by muse, mutect2, varscan2
- OXCT1 | c.672G>A p.R224= | Splice Region (SNP) | VAF 83/434 reads (19%) | catalogued as COSV52170184; called by muse, mutect2, varscan2
- PCDH18 | c.2549G>A p.R850Q | Missense Mutation (SNP) | VAF 88/441 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs1430122137, COSV61267510; called by muse, mutect2, varscan2
- PCDHB13 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 430/1081 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.443); catalogued as rs782331919, COSV53402802; called by muse, mutect2, varscan2
- PCDHB8 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 59/673 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1244749686; called by muse, mutect2, varscan2
- PCDHB8 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 279/2538 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV50795656; called by muse, mutect2, varscan2
- PCDHB8 | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 344/3220 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.33); catalogued as COSV99177251; called by muse, mutect2, varscan2
- PCDHGA2 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 205/511 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV53907669, COSV53920867; called by muse, mutect2, varscan2
- PCDHGA5 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 124/558 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs912689186, COSV53898317; called by muse, mutect2, varscan2
- PCDHGB5 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 202/481 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs368407532, COSV53973969; called by muse, mutect2, varscan2
- PCLO | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 109/407 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.434); catalogued as rs866533946, COSV61625352; called by muse, mutect2, varscan2
- PCSK6 | c.2548C>T p.H850Y | Missense Mutation (SNP) | VAF 72/378 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV61860387; called by muse, mutect2, varscan2
- PDE1C | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 77/330 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs754743229, COSV58514457, COSV58518309; called by muse, mutect2, varscan2
- PDZD8 | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 111/337 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368320672, COSV53688327; called by muse, mutect2, varscan2
- PDZRN4 | c.1420G>A p.D474N (on ENST00000402685 / NM_001164595.2; = p.D216N on NM_013377.4) | Missense Mutation (SNP) | VAF 84/370 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs773487228; called by muse, mutect2, varscan2
- PGK2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 121/600 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV59166009; called by muse, mutect2, varscan2
- PHF24 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 98/462 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201860472; called by muse, mutect2, varscan2
- PIEZO2 | c.7928C>T p.P2643L | Missense Mutation (SNP) | VAF 109/627 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs367943583; called by muse, mutect2, varscan2
- PLCB1 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 109/437 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs771607069, COSV62055161; called by muse, mutect2, varscan2
- POLN | c.1615C>T p.H539Y | Missense Mutation (SNP) | VAF 72/299 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs755638925; called by muse, mutect2, varscan2
- PPFIA3 | c.2181G>A p.M727I | Missense Mutation (SNP) | VAF 165/479 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV61952239; called by muse, mutect2, varscan2
- PRAMEF14 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.432); catalogued as rs1357730808; called by muse, mutect2, varscan2
- PRKN | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 139/350 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58213605; called by muse, mutect2, varscan2
- PRR5 | c.706C>T p.R236C (on ENST00000336985 / NM_181333.4; = p.R227C on NM_015366.4) | Missense Mutation (SNP) | VAF 77/300 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); catalogued as rs756128125, COSV50060201; called by muse, mutect2, varscan2
- PRSS1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 104/1057 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV61196626; called by muse, mutect2
- PSMD13 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 84/402 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1180158059; called by muse, mutect2, varscan2
- PTPN1 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 95/394 reads (24%) | catalogued as rs370578341; called by muse, mutect2, varscan2
- PTPRD | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 84/326 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as rs1370111525, COSV61978781; called by muse, mutect2, varscan2
- PUF60 | c.613C>T p.P205S (on ENST00000526683 / NM_001362896.2; = p.P188S on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1439430129; called by muse, mutect2, varscan2
- RALB | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV55602458, COSV55603316; called by muse, mutect2, varscan2
- RFX4 | c.793G>A p.G265R (on ENST00000392842 / NM_213594.3; = p.G171R on NM_032491.6) | Missense Mutation (SNP) | VAF 218/505 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1472123079; called by muse, mutect2, varscan2
- RFX7 | c.1042C>T p.R348C (on ENST00000559447 / NM_001368074.1; = p.R445C on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/227 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs764160839, COSV57968710; called by muse, mutect2, varscan2
- ROR2 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 105/391 reads (27%) | catalogued as rs943841260; called by muse, mutect2, varscan2
- ROS1 | c.2814G>A p.G938= | Splice Region (SNP) | VAF 37/116 reads (32%) | catalogued as COSV63851428; called by muse, mutect2, varscan2
- RP1 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 120/505 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1454376137, COSV55112816; called by muse, mutect2, varscan2
- RP1 | c.4060G>A p.D1354N | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV55114413; called by muse, mutect2, varscan2
- RRAD | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 145/378 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.626); catalogued as COSV55340133; called by muse, mutect2, varscan2
- RUNX1T1 | c.445C>T p.R149C (on ENST00000265814 / NM_001198628.1; = p.R122C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354844348, COSV99751260; called by muse, mutect2, varscan2
- SALL1 | c.3161G>A p.R1054Q | Missense Mutation (SNP) | VAF 109/342 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as rs766340574, COSV51756131; called by muse, mutect2, varscan2
- SAMM50 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as rs769314961, COSV63110147; called by muse, mutect2, varscan2
- SBNO2 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 147/583 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs995340988; called by muse, mutect2, varscan2
- SCN2A | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 64/285 reads (22%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.999); catalogued as rs1182447925, COSV99330304; called by muse, mutect2, varscan2
- SLC15A5 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 99/406 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.704); catalogued as rs970908027; called by muse, mutect2, varscan2
- SLC16A9 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV68098318; called by muse, mutect2, varscan2
- SLC17A3 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 86/483 reads (18%) | catalogued as rs1375115698; called by muse, mutect2, varscan2
- SLC27A6 | c.688C>T p.L230= | Splice Region (SNP) | VAF 67/339 reads (20%) | catalogued as COSV99323264; called by muse, mutect2, varscan2
- SLC27A6 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 107/291 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs760437774, COSV99322940; called by muse, mutect2, varscan2
- SLC35A5 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 100/470 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995600124; called by muse, mutect2, varscan2
- SLC3A1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 139/518 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199700629, COSV53224440, COSV99577259; called by muse, mutect2, varscan2
- SLC44A3 | c.446C>T p.S149F (on ENST00000271227 / NM_001114106.3; = p.S101F on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99598105; called by muse, mutect2, varscan2
- SLC9A2 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 146/501 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs529065601, COSV52129399; called by muse, mutect2, varscan2
- SLIT3 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 250/714 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415877188, COSV60604140; called by muse, mutect2
- SLITRK6 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV68389409; called by muse, mutect2, varscan2
- SLITRK6 | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1367563006; called by muse, mutect2, varscan2
- SMARCB1 | c.883C>T p.R295W (on ENST00000263121; = p.R341W on NM_003073.5) | Missense Mutation (SNP) | VAF 114/411 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772804160, CD123781, COSV51955110; called by muse, varscan2
- SNX11 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 125/558 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs772474027; called by muse, mutect2, varscan2
- SPACA7 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 123/370 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs1244291109, COSV52098307; called by muse, mutect2, varscan2
- SPATA31A1 | c.2762G>A p.R921K | Missense Mutation (SNP) | VAF 56/406 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as rs1472220742; called by muse, mutect2, varscan2
- SPATA31D4 | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 106/522 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs746019337, COSV59384080; called by muse, mutect2, varscan2
- SPEM2 | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 148/461 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs760478506; called by muse, mutect2, varscan2
- SPIDR | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 109/408 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.697); catalogued as COSV52376453; called by muse, mutect2, varscan2
- SPN | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 103/401 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs181483014, COSV64070418; called by muse, mutect2, varscan2
- SSBP2 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 57/376 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs766076142; called by muse, mutect2, varscan2
- ST6GAL2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 73/270 reads (27%) | PolyPhen probably damaging (0.986); catalogued as COSV100868113; called by muse, mutect2, varscan2
- STIL | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 101/391 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as rs746327335, COSV99680829; called by muse, mutect2, varscan2
- STING1 | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 204/489 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs749059030; called by muse, mutect2, varscan2
- SUSD5 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 108/392 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs776179774, COSV58875454; called by muse, mutect2, varscan2
- SV2B | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 103/503 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as COSV57700808; called by muse, mutect2, varscan2
- SVEP1 | c.6178C>T p.L2060F | Missense Mutation (SNP) | VAF 105/364 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1484560022, COSV52844314, COSV99927936; called by muse, mutect2, varscan2
- SYNE1 | c.11138C>T p.S3713F (on ENST00000367255 / NM_182961.4; = p.S3698F on NM_033071.3) | Missense Mutation (SNP) | VAF 124/531 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV55096355, COSV55115259; called by muse, mutect2, varscan2
- SYNJ2 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 96/569 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753556219; called by muse, mutect2, varscan2
- TAS1R1 | c.623G>A p.W208* | Nonsense Mutation (SNP) | VAF 142/558 reads (25%) | catalogued as COSV60229683; called by muse, mutect2, varscan2
- TBX15 | c.515G>A p.R172K (on ENST00000369429 / NM_001330677.2; = p.R66K on NM_152380.3) | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV52873684; called by muse, mutect2, varscan2
- TBX18 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 104/425 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1160240401, COSV63738734; called by muse, mutect2, varscan2
- TENM2 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 109/307 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.993); catalogued as rs373360913, COSV69133439; called by muse, mutect2, varscan2
- TENM3 | c.7801G>A p.G2601S | Missense Mutation (SNP) | VAF 123/472 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.638); catalogued as COSV99073215; called by muse, mutect2, varscan2
- TGM1 | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 111/416 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767855778, COSV52863291; called by muse, mutect2, varscan2
- THEMIS | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 111/394 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV64069513; called by muse, mutect2, varscan2
- THSD7B | c.2705G>A p.R902K | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV55721579; called by muse, mutect2, varscan2
- TMC2 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 91/392 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62649388; called by muse, mutect2, varscan2
- TMEM132A | c.2815G>A p.G939S (on ENST00000453848 / NM_178031.3; = p.G940S on NM_017870.4) | Missense Mutation (SNP) | VAF 183/639 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs762597307; called by muse, mutect2, varscan2
- TMEM132C | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 106/440 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs758641133, COSV59425610; called by muse, varscan2
- TMEM151A | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 158/567 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV59173810; called by muse, varscan2
- TMEM222 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 94/422 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.074); catalogued as rs754715407, COSV65027003; called by muse, mutect2, varscan2
- TMIGD3 | c.235A>C p.K79Q (on ENST00000369717 / NM_001081976.2; = p.K160Q on NM_020683.7) | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1447200401; called by muse, mutect2, varscan2
- TNFSF11 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 46/220 reads (21%) | catalogued as rs764386548, COSV53476775; called by muse, mutect2, varscan2
- TNRC6A | c.5257C>T p.R1753C | Missense Mutation (SNP) | VAF 76/338 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1002813156; called by muse, mutect2, varscan2
- TRANK1 | c.7444C>T p.L2482F | Missense Mutation (SNP) | VAF 143/466 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV57154273; called by muse, mutect2, varscan2
- TRBV28 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs745393218; called by muse, mutect2, varscan2
- TRMO | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 82/353 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.056); catalogued as rs775767150; called by muse, mutect2, varscan2
- TRPC6 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.89); catalogued as COSV60258707; called by muse, mutect2, varscan2
- TRPM6 | c.4999G>A p.D1667N | Missense Mutation (SNP) | VAF 69/324 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs763702052; called by muse, mutect2, varscan2
- TRPM6 | c.2114C>T p.S705L | Missense Mutation (SNP) | VAF 107/422 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.509); catalogued as rs753358405, COSV100666426; called by muse, mutect2, varscan2
- TTBK1 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 126/653 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.017); catalogued as rs760249935, COSV52491563; called by mutect2, varscan2
- TTLL13P | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 250/528 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs148583428; called by muse, mutect2, varscan2
- TTN | c.76801G>A p.E25601K (on ENST00000591111; = p.E18177K on NM_003319.4) | Missense Mutation (SNP) | VAF 101/426 reads (24%) | PolyPhen probably damaging (0.994); catalogued as rs868349549, COSV60184347; called by muse, mutect2, varscan2
- TTN | c.75656G>A p.G25219E (on ENST00000591111; = p.G17795E on NM_003319.4) | Missense Mutation (SNP) | VAF 97/353 reads (27%) | PolyPhen probably damaging (1); catalogued as COSV59905157; called by muse, mutect2, varscan2
- TTN | c.54755C>T p.S18252L (on ENST00000591111; = p.S10828L on NM_003319.4) | Missense Mutation (SNP) | VAF 78/351 reads (22%) | PolyPhen probably damaging (0.996); catalogued as rs766590578, COSV60363943; called by muse, mutect2, varscan2
- TTN | c.12739G>A p.E4247K (on ENST00000591111; = p.E4201K on NM_003319.4) | Missense Mutation (SNP) | VAF 98/380 reads (26%) | catalogued as rs746672079, COSV60169973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.7711G>A p.E2571K (on ENST00000591111; = p.E2525K on NM_003319.4) | Missense Mutation (SNP) | VAF 98/418 reads (23%) | PolyPhen benign (0.033); catalogued as rs149660690, COSV60136909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.6991G>A p.E2331K (on ENST00000591111; = p.E2285K on NM_003319.4) | Missense Mutation (SNP) | VAF 118/447 reads (26%) | PolyPhen possibly damaging (0.54); catalogued as COSV59998929; called by muse, mutect2, varscan2
- UBA6 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs375294484; called by muse, mutect2, varscan2
- UBE3D | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 74/319 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139706098; called by muse, mutect2, varscan2
- UGT1A5 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs776921440; called by muse, mutect2, varscan2
- ULK2 | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV64447395; called by muse, mutect2, varscan2
- UNC13B | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 109/338 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV65934917; called by muse, mutect2, varscan2
- UNC5B | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 65/285 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs1247435132; called by muse, mutect2, varscan2
- UROC1 | c.1893G>A p.V631= | Splice Region (SNP) | VAF 160/364 reads (44%) | catalogued as rs1270031834; called by muse, mutect2, varscan2
- USH1C | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 91/369 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV50020121; called by muse, mutect2, varscan2
- USP26 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 123/248 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs755327016, COSV100896720; called by muse, mutect2, varscan2
- VAT1L | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 85/288 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV56829590; called by muse, mutect2, varscan2
- VAV1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 99/407 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs749873161, COSV58383552, COSV58390451; called by muse, mutect2, varscan2
- VPREB1 | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 109/451 reads (24%) | catalogued as rs1482927285; called by muse, mutect2, varscan2
- VWA8 | c.2987C>T p.S996F | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV55701697; called by muse, mutect2, varscan2
- VWC2 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 120/479 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs748580294, COSV99080282; called by muse, mutect2, varscan2
- WFIKKN2 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 149/506 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV60958648; called by muse, mutect2, varscan2
- WNT5A | c.775T>C p.F259L | Missense Mutation (SNP) | VAF 79/427 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1269552696; called by muse, mutect2, varscan2
- WNT7B | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 119/458 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59750703; called by muse, mutect2, varscan2
- ZC2HC1B | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 203/456 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs866910730; called by muse, mutect2, varscan2
- ZFHX4 | c.5167C>T p.P1723S | Missense Mutation (SNP) | VAF 119/454 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs866599341, COSV50512080, COSV51476340; called by muse, mutect2, varscan2
- ZFP64 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 107/489 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs771244712, COSV99402904; called by muse, mutect2, varscan2
- ZMYM5 | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.971); catalogued as rs1224883950; called by muse, mutect2, varscan2
- ZNF165 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 188/503 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as rs768904168; called by muse, mutect2, varscan2
- ZNF516 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 115/485 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1404733646; called by muse, mutect2, varscan2
- ZNF541 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1024358039, COSV99645485; called by muse, mutect2, varscan2
- ZNF679 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.986); catalogued as COSV55376137; called by muse, mutect2, varscan2
- ZNF764 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 163/563 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99411063; called by muse, mutect2, varscan2
- ZNF792 | c.1656C>A p.H552Q | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV68692887; called by muse, mutect2, varscan2
- ZNF804A | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 101/398 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV56436414, COSV56441451; called by muse, mutect2, varscan2
- ZNF99 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 99/387 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV68055691; called by muse, mutect2, varscan2
- ABCA9 | c.4310G>A p.G1437E | Missense Mutation (SNP) | VAF 125/436 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS20 | c.1646A>G p.E549G | Missense Mutation (SNP) | VAF 94/337 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ADAMTSL2 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 97/384 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADARB2 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 157/555 reads (28%) | called by muse, mutect2, varscan2
- ADGRE5 | c.1061C>T p.S354F (on ENST00000242786 / NM_078481.4; = p.S261F on NM_001784.5) | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- AFDN | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 157/398 reads (39%) | called by muse, mutect2, varscan2
- AGBL2 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 103/356 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ALAS1 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 70/262 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ALDH2 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- AMPH | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ANK3 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 101/271 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD30A | c.2969A>T p.E990V (on ENST00000611781; = p.E934V on NM_052997.2) | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ANKUB1 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ANO4 | c.1631A>T p.N544I (on ENST00000392977 / NM_001286615.2; = p.N509I on NM_178826.4) | Missense Mutation (SNP) | VAF 193/490 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- AP1M2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP3B2 | c.2557G>A p.V853I (on ENST00000261722; = p.V847I on NM_004644.5) | Missense Mutation (SNP) | VAF 73/303 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AP3D1 | c.2402C>T p.A801V | Missense Mutation (SNP) | VAF 72/332 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- APELA | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT tolerated, low confidence (0.27); called by muse, mutect2, varscan2
- ARFGEF3 | c.5875G>A p.E1959K | Missense Mutation (SNP) | VAF 414/854 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARHGAP24 | c.866C>A p.A289E (on ENST00000395184 / NM_001025616.3; = p.A196E on NM_031305.3) | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ARHGAP44 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ART5 | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 115/505 reads (23%) | called by muse, mutect2, varscan2
- ASB6 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 173/618 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATF6B | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 78/459 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- BAG6 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 182/1022 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BBS4 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BCLAF3 | c.1274+1G>A p.X425_splice | Splice Site (SNP) | VAF 63/94 reads (67%) | called by muse, mutect2, varscan2
- BCLAF3 | c.1274G>A p.R425K | Missense Mutation (SNP) | VAF 64/97 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- BHMT2 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 95/495 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMP7 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 146/526 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- BPHL | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 83/329 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BPTF | c.4342C>T p.R1448* | Nonsense Mutation (SNP) | VAF 128/453 reads (28%) | called by muse, mutect2, varscan2
- BRSK2 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 97/342 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- C12orf50 | c.373T>A p.Y125N | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C1orf94 | c.1271-1G>A p.X424_splice (on ENST00000488417 / NM_001134734.2; = p.X234_splice on NM_032884.5) | Splice Site (SNP) | VAF 51/193 reads (26%) | called by muse, mutect2, varscan2
- C2orf16 | c.3448C>T p.P1150S | Missense Mutation (SNP) | VAF 71/319 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- C2orf16 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 100/409 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CA2 | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 108/389 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACHD1 | c.580G>C p.G194R | Missense Mutation (SNP) | VAF 12/401 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1E | c.3422C>T p.P1141L | Missense Mutation (SNP) | VAF 147/283 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- CACNA1G | c.4204G>T p.V1402L | Missense Mutation (SNP) | VAF 20/493 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- CALCRL | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 64/231 reads (28%) | called by muse, mutect2, varscan2
- CALN1 | c.215C>T p.P72L (on ENST00000329008 / NM_001017440.3; = p.P114L on NM_031468.4) | Missense Mutation (SNP) | VAF 142/502 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CALN1 | c.214C>T p.P72S (on ENST00000329008 / NM_001017440.3; = p.P114S on NM_031468.4) | Missense Mutation (SNP) | VAF 144/505 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CAPN14 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 108/422 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CARNMT1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 96/393 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CBY2 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 111/453 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CCDC144A | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- CCDC188 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 124/518 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CCDC191 | c.1937G>A p.R646K | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD209 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 160/735 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- CD40 | c.704A>G p.E235G | Missense Mutation (SNP) | VAF 111/357 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- CDK5RAP3 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 103/429 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPB | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CEP250 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 77/344 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CFAP57 | c.301A>G p.N101D | Missense Mutation (SNP) | VAF 133/433 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP69 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- CFAP70 | c.1371del p.Q458Sfs*4 | Frame Shift Del (DEL) | VAF 88/282 reads (31%) | called by mutect2, pindel*, varscan2
- CFAP91 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CIDEA | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 276/721 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CLEC4F | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 101/431 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CLEC9A | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CLPSL1 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 62/493 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- CMYA5 | c.5047G>A p.E1683K | Missense Mutation (SNP) | VAF 177/496 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CMYA5 | c.9848G>A p.W3283* | Nonsense Mutation (SNP) | VAF 82/440 reads (19%) | called by muse, mutect2, varscan2
- COASY | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 106/498 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL12A1 | c.8171C>T p.P2724L | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL27A1 | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 103/517 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- COL2A1 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 112/429 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL7A1 | c.4717G>A p.E1573K | Missense Mutation (SNP) | VAF 100/391 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- COPG1 | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 78/469 reads (17%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CP | c.1001G>A p.W334* | Nonsense Mutation (SNP) | VAF 114/387 reads (29%) | called by muse, mutect2, varscan2
- DAPP1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- DCAF6 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 119/446 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DCHS1 | c.5599G>A p.D1867N | Missense Mutation (SNP) | VAF 119/453 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- DDN | c.1166C>A p.S389Y | Missense Mutation (SNP) | VAF 149/570 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DDX41 | c.703T>C p.F235L | Missense Mutation (SNP) | VAF 127/591 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- DDX5 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 78/298 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- DHRS9 | c.190T>A p.S64T | Missense Mutation (SNP) | VAF 140/484 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DICER1 | c.5188G>A p.G1730R | Missense Mutation (SNP) | VAF 195/390 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIPK1A | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 147/465 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DMXL1 | c.8044G>A p.D2682N | Missense Mutation (SNP) | VAF 148/394 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DNAAF5 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 150/522 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DNAH10 | c.4573G>A p.E1525K (on ENST00000409039; = p.E1464K on NM_207437.3) | Missense Mutation (SNP) | VAF 114/431 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAH12 | c.8351C>T p.S2784F (on ENST00000351747; = p.S3652F on NM_001366028.2) | Missense Mutation (SNP) | VAF 79/326 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- DNAH2 | c.6899G>A p.G2300E | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- DNAH2 | c.7325T>C p.V2442A | Missense Mutation (SNP) | VAF 87/221 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH7 | c.9944C>T p.P3315L | Missense Mutation (SNP) | VAF 93/348 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.3998G>A p.G1333E | Missense Mutation (SNP) | VAF 93/412 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.2014A>T p.K672* | Nonsense Mutation (SNP) | VAF 79/255 reads (31%) | called by muse, mutect2, varscan2
- DOCK10 | c.1324T>A p.F442I | Missense Mutation (SNP) | VAF 109/370 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DSC2 | c.2299G>A p.G767R | Missense Mutation (SNP) | VAF 121/375 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DSCAM | c.3797C>T p.S1266L | Missense Mutation (SNP) | VAF 139/369 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DST | c.21881C>T p.P7294L (on ENST00000361203 / NM_001374722.1; = p.P4967L on NM_015548.5) | Missense Mutation (SNP) | VAF 136/707 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- DYM | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 76/312 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- DYNC1H1 | c.6268C>T p.L2090F | Missense Mutation (SNP) | VAF 195/378 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2I1 | c.2353C>T p.P785S | Missense Mutation (SNP) | VAF 130/265 reads (49%) | SIFT tolerated (0.67); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ECEL1 | c.923A>C p.Q308P | Missense Mutation (SNP) | VAF 128/476 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- EEA1 | c.2402del p.K801Sfs*12 | Frame Shift Del (DEL) | VAF 55/544 reads (10%) | called by mutect2, pindel, varscan2
- EGF | c.2884G>A p.E962K | Missense Mutation (SNP) | VAF 93/361 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EIF4G3 | c.4250C>T p.S1417L | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELMO3 | c.2090T>A p.I697N (on ENST00000652269; = p.I644N on NM_024712.5) | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- EMILIN2 | c.1712G>T p.R571M | Missense Mutation (SNP) | VAF 32/845 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2
- EML6 | c.1205T>C p.V402A | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- ERV3-1 | c.1514A>G p.Y505C | Missense Mutation (SNP) | VAF 84/397 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ESPN | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 48/284 reads (17%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ETV3L | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 188/374 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVX1 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 161/590 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAF1 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FAM153B | c.457C>T p.P153S (on ENST00000253490; = p.P76S on NM_001265615.1) | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83H | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 119/547 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM83H | c.2710C>T p.P904S | Missense Mutation (SNP) | VAF 116/542 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- FANCA | c.1727G>A p.R576K | Missense Mutation (SNP) | VAF 99/263 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- FANCM | c.3316C>T p.P1106S | Missense Mutation (SNP) | VAF 79/323 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- FASTKD1 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 87/349 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FBXL18 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 131/509 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- FBXO22 | c.800C>G p.P267R | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- FGR | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FMNL2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 85/326 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FOXD4L5 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 148/1253 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FREM3 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 153/685 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GABBR1 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 449/1094 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- GGNBP2 | c.2040T>G p.N680K | Missense Mutation (SNP) | VAF 130/489 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GHSR | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 266/600 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- GJA10 | c.1128A>T p.R376S | Missense Mutation (SNP) | VAF 112/434 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GNB3 | c.633G>A p.W211* | Nonsense Mutation (SNP) | VAF 107/479 reads (22%) | called by muse, mutect2, varscan2
- GOLGA6D | c.1739A>G p.N580S | Missense Mutation (SNP) | VAF 55/389 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- GREB1L | c.4835C>T p.P1612L | Missense Mutation (SNP) | VAF 94/413 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRHL2 | c.1779G>A p.M593I | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- GRXCR2 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 154/657 reads (23%) | called by muse, mutect2, varscan2
- HDAC4 | c.2029G>T p.E677* | Nonsense Mutation (SNP) | VAF 135/542 reads (25%) | called by muse, mutect2, varscan2
- HECTD4 | c.8983C>T p.P2995S | Missense Mutation (SNP) | VAF 103/394 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- HELZ2 | c.6386C>T p.P2129L (on ENST00000467148 / NM_001037335.2; = p.P1560L on NM_033405.3) | Missense Mutation (SNP) | VAF 89/401 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HIVEP3 | c.2414C>T p.S805F | Missense Mutation (SNP) | VAF 109/396 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HOXC10 | c.806G>A p.R269K | Missense Mutation (SNP) | VAF 132/483 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- HRC | c.1262G>A p.R421K | Missense Mutation (SNP) | VAF 164/384 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- HSD3B1 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 108/487 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- HSPA2 | c.1396G>T p.G466W | Missense Mutation (SNP) | VAF 102/296 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IDO2 | c.764G>A p.G255E (on ENST00000389060; = p.G268E on NM_194294.2) | Missense Mutation (SNP) | VAF 118/313 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNA17 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 25/419 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2
- IGHV3-74 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- IGSF9 | c.2929C>T p.P977S (on ENST00000368094 / NM_001135050.2; = p.P961S on NM_020789.4) | Missense Mutation (SNP) | VAF 319/561 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IHO1 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 114/516 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IKZF2 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 131/478 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IL27 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 144/509 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS2 | c.1885C>T p.Q629* | Nonsense Mutation (SNP) | VAF 63/258 reads (24%) | called by muse, mutect2, varscan2
- IQCB1 | c.1327C>G p.P443A | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IRX1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 197/434 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, varscan2
- ITGAE | c.68T>G p.V23G | Missense Mutation (SNP) | VAF 102/226 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- KCNJ1 | c.784T>C p.F262L | Missense Mutation (SNP) | VAF 126/341 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNQ2 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 135/451 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KCNT2 | c.1924C>T p.Q642* | Nonsense Mutation (SNP) | VAF 105/321 reads (33%) | called by muse, mutect2, varscan2
- KIAA0895L | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 116/302 reads (38%) | called by muse, mutect2, varscan2
- KIAA1549L | c.4444C>T p.P1482S (on ENST00000321505; = p.P1779S on NM_012194.3) | Missense Mutation (SNP) | VAF 121/446 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1549L | c.4445C>T p.P1482L (on ENST00000321505; = p.P1779L on NM_012194.3) | Missense Mutation (SNP) | VAF 121/452 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF4B | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 139/773 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL9 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KMT2A | c.1225T>A p.F409I | Missense Mutation (SNP) | VAF 112/275 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KRT71 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRT9 | c.1501_1527del p.G501_G509del | In Frame Del (DEL) | VAF 144/632 reads (23%) | called by mutect2, varscan2
- KRTAP29-1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 151/574 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- LAMA1 | c.5156C>T p.T1719I | Missense Mutation (SNP) | VAF 53/408 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LARP4 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 108/378 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LATS2 | c.2537C>T p.S846F | Missense Mutation (SNP) | VAF 127/458 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- LCE1F | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 171/589 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- LILRB1 | c.1681G>A p.E561K (on ENST00000427581; = p.E511K on NM_006669.6) | Missense Mutation (SNP) | VAF 83/291 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- LMO1 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LMOD2 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 109/451 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.1614G>A p.M538I | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LY9 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LYRM4 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 77/409 reads (19%) | called by muse, mutect2, varscan2
- LYST | c.3112T>A p.L1038I | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MAGEB6B | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 118/219 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MAS1L | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 176/779 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MAST2 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 111/496 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MGAM | c.1910G>A p.R637K | Missense Mutation (SNP) | VAF 91/633 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MKS1 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- MLLT6 | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 169/724 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MOV10L1 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 100/371 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MRPL38 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 93/458 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MS4A12 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 92/438 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.04); called by muse, mutect2
- MSI1 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 150/571 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- MTERF4 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 124/536 reads (23%) | called by muse, mutect2, varscan2
- MUC16 | c.31290G>A p.M10430I | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC3A | c.8835G>A p.M2945I | Missense Mutation (SNP) | VAF 93/529 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC5B | c.12245C>T p.P4082L | Missense Mutation (SNP) | VAF 223/866 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MYADML2 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 156/623 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH4 | c.4448C>T p.T1483I | Missense Mutation (SNP) | VAF 106/305 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYO15A | c.7116A>G p.Q2372= | Splice Region (SNP) | VAF 77/307 reads (25%) | called by muse, mutect2, varscan2
- NAA11 | c.632A>C p.E211A | Missense Mutation (SNP) | VAF 72/389 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- NAV3 | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 100/377 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- NBEAL2 | c.5663C>T p.P1888L | Missense Mutation (SNP) | VAF 147/553 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NCOR2 | c.1928C>T p.S643F | Missense Mutation (SNP) | VAF 108/460 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NELL2 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- NF1 | c.6380_6396del p.I2127Tfs*10 (on ENST00000358273 / NM_001042492.3; = p.I2106Tfs*10 on NM_000267.3) | Frame Shift Del (DEL) | VAF 72/259 reads (28%) | called by mutect2, pindel, varscan2
- NFYB | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 85/402 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- NME1-NME2 | c.308G>T p.W103L (on ENST00000555572; = p.W78L on NM_001018136.3) | Missense Mutation (SNP) | VAF 121/499 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- NOP56 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 78/327 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.332); called by muse, varscan2
- NPEPPS | c.1075T>C p.F359L | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPY | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NR2C1 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NR4A1 | c.1161C>T p.F387= | Splice Region (SNP) | VAF 77/302 reads (25%) | called by muse, mutect2, varscan2
- NUDT5 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUTM2B | c.2530G>A p.G844R | Missense Mutation (SNP) | VAF 127/1106 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- NXPE2 | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 101/416 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- OBSCN | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 168/391 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- OR14K1 | c.911G>A p.W304* | Nonsense Mutation (SNP) | VAF 74/184 reads (40%) | called by muse, mutect2, varscan2
- OR1B1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 100/403 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- OR2A2 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 239/652 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- OR2L8 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 85/253 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- OR4Q3 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 92/552 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OR4Q3 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 123/571 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- OR5B2 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 73/323 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- OR5W2 | c.644T>A p.F215Y | Missense Mutation (SNP) | VAF 81/353 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- OR8H2 | c.838A>T p.I280F | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OTOG | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 98/433 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- OTOG | c.6625G>A p.D2209N | Missense Mutation (SNP) | VAF 106/430 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- OTX2 | c.437G>A p.S146N (on ENST00000408990 / NM_172337.3; = p.S154N on NM_021728.4) | Missense Mutation (SNP) | VAF 151/579 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- P2RY8 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 201/713 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PACSIN1 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 142/829 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAOX | c.663T>A p.F221L | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PAX4 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 106/504 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PCDH9 | c.3331C>T p.P1111S (on ENST00000377865 / NM_203487.3; = p.P1077S on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB3 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 350/926 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PCDHB6 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 294/812 reads (36%) | called by muse, varscan2
- PCDHGA12 | c.2263C>T p.H755Y | Missense Mutation (SNP) | VAF 249/645 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PCDHGC3 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 188/547 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCLO | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 121/475 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- PCSK1N | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 188/319 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PDK2 | c.1088_1091delinsGTT p.L363Rfs*94 | Frame Shift Del (DEL) | VAF 71/398 reads (18%) | called by pindel, varscan2*
- PGR | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 90/368 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- PKD1 | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 126/486 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PKHD1L1 | c.3643G>A p.V1215I | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.122); called by muse, mutect2
- PLCL2 | c.2653G>A p.G885R (on ENST00000615277 / NM_001144382.2; = p.G759R on NM_015184.5) | Missense Mutation (SNP) | VAF 76/352 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLIN4 | c.3268G>A p.E1090K (on ENST00000301286; = p.E1105K on NM_001367868.2) | Missense Mutation (SNP) | VAF 127/571 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLK2 | c.1291G>T p.G431* | Nonsense Mutation (SNP) | VAF 95/394 reads (24%) | called by muse, mutect2, varscan2
- POLQ | c.1054A>T p.K352* | Nonsense Mutation (SNP) | VAF 88/352 reads (25%) | called by muse, mutect2, varscan2
- PPIL2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 80/385 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRC2A | c.3964G>A p.E1322K | Missense Mutation (SNP) | VAF 208/934 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PTPRB | c.3922C>T p.P1308S | Missense Mutation (SNP) | VAF 129/541 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRQ | c.4870G>A p.E1624K (on ENST00000616559; = p.E1582K on NM_001145026.2) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- RAPGEF5 | c.1042G>A p.D348N (on ENST00000401957 / NM_001367602.2; = p.D651N on NM_012294.5) | Missense Mutation (SNP) | VAF 94/354 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RB1CC1 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 57/280 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RBMY1A1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 95/1012 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.269); called by muse, mutect2
- RET | c.2699A>C p.Y900S | Missense Mutation (SNP) | VAF 100/366 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGPD4 | c.4814C>T p.S1605L | Missense Mutation (SNP) | VAF 108/435 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RNF17 | c.4328A>G p.H1443R | Missense Mutation (SNP) | VAF 80/348 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- RP1 | c.6269A>T p.N2090I | Missense Mutation (SNP) | VAF 95/375 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- RP1 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 107/353 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPE65 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 59/283 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RPH3A | c.445-1G>A p.X149_splice (on ENST00000389385 / NM_001143854.2; = p.X145_splice on NM_014954.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 62/254 reads (24%) | called by muse, varscan2
- RPS6KA2 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 76/388 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RREB1 | c.3569C>T p.T1190I | Missense Mutation (SNP) | VAF 88/529 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- RRS1 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 176/640 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RSPH6A | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 84/240 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SAMD7 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SCN1A | c.4955G>A p.G1652E (on ENST00000303395 / NM_001202435.3; = p.G1641E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/524 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SCN5A | c.1720G>A p.G574R | Missense Mutation (SNP) | VAF 149/597 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- SCN7A | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 104/367 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, varscan2
- SDC1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 104/347 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SEC16B | c.2236C>T p.Q746* | Nonsense Mutation (SNP) | VAF 168/305 reads (55%) | called by muse, mutect2, varscan2
- SFMBT1 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SHKBP1 | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 81/274 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM1 | c.2467G>T p.D823Y (on ENST00000378679 / NM_001172700.2; = p.D818Y on NM_133456.2) | Missense Mutation (SNP) | VAF 244/686 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIGLEC7 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 133/377 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- SKOR2 | c.2681A>C p.K894T (on ENST00000425639 / NM_001278063.4; = p.R260= on NM_001037802.3) | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- SLC10A6 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 80/329 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- SLC17A4 | c.1377G>A p.W459* | Nonsense Mutation (SNP) | VAF 143/365 reads (39%) | called by muse, mutect2, varscan2
- SLC1A1 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 26/313 reads (8%) | called by muse, mutect2
- SLC22A24 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SLC2A13 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SLC4A5 | c.2863G>A p.V955M | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLC6A2 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 142/391 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC9A5 | c.2607G>A p.M869I | Missense Mutation (SNP) | VAF 93/302 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- SLC9A5 | c.2608G>A p.G870S | Missense Mutation (SNP) | VAF 95/301 reads (32%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLFN14 | c.1042A>C p.M348L | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMC2 | c.3334C>T p.L1112F | Missense Mutation (SNP) | VAF 101/403 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMTNL1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 71/290 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- SPHKAP | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 134/481 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SPNS1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 153/584 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SSU72P2 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 84/530 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ST6GALNAC5 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 104/388 reads (27%) | PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- STK17B | c.368T>C p.L123S | Missense Mutation (SNP) | VAF 90/311 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SUCO | c.3717_3718del p.E1239Dfs*49 | Frame Shift Del (DEL) | VAF 167/466 reads (36%) | called by pindel, varscan2
- SUPT16H | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 90/290 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- SVIL | c.3107C>T p.P1036L (on ENST00000355867 / NM_021738.3; = p.P610L on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/525 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SVOP | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SWSAP1 | c.358G>A p.D120N (on ENST00000312423; = p.D141N on NM_175871.4) | Missense Mutation (SNP) | VAF 150/598 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TACC2 | c.4579G>A p.E1527K | Missense Mutation (SNP) | VAF 131/382 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TEX13D | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 77/136 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- TIAM2 | c.3106A>T p.S1036C | Missense Mutation (SNP) | VAF 55/396 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TICAM1 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 152/581 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TLE2 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 87/327 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TM4SF4 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 98/441 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- TMEM178B | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 84/232 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM71 | c.655G>A p.E219K (on ENST00000523829 / NM_001382398.1; = p.E200K on NM_144649.3) | Missense Mutation (SNP) | VAF 79/312 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMPRSS7 | c.400C>T p.L134F (on ENST00000452346; = p.L22F on NM_001042575.2) | Missense Mutation (SNP) | VAF 99/451 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TNR | c.1702T>C p.S568P | Missense Mutation (SNP) | VAF 231/469 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TNS4 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 89/414 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TPI1 | c.809G>A p.G270D (on ENST00000229270; = p.G233D on NM_000365.6) | Missense Mutation (SNP) | VAF 50/452 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- TPTE | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 106/631 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- TRAJ23 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 81/317 reads (26%) | called by muse, mutect2, varscan2
- TRAT1 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRAV1-2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- TRAV7 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- TRIM24 | c.2894T>A p.F965Y (on ENST00000343526 / NM_015905.3; = p.F931Y on NM_003852.4) | Missense Mutation (SNP) | VAF 135/480 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- TRIM55 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 92/360 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TRPM2 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 122/356 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TRPM5 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 184/654 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTC21B | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTC5 | c.917A>T p.D306V | Missense Mutation (SNP) | VAF 127/459 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTI1 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 96/374 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, varscan2
- TTLL5 | c.2906C>T p.T969I | Missense Mutation (SNP) | VAF 126/346 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- TTN | c.96442G>A p.A32148T (on ENST00000591111; = p.A24724T on NM_003319.4) | Missense Mutation (SNP) | VAF 107/432 reads (25%) | PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TTN | c.41399A>T p.D13800V (on ENST00000591111; = p.D6376V on NM_003319.4) | Missense Mutation (SNP) | VAF 45/206 reads (22%) | PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- TTN | c.21652G>A p.E7218K (on ENST00000591111; = p.E6291K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/460 reads (23%) | PolyPhen benign (0.225); called by muse, mutect2, varscan2
- UBE2C | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 84/361 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UPRT | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VSX2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 113/331 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNK2 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 126/606 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WNT16 | c.911G>A p.G304E (on ENST00000222462 / NM_057168.2; = p.G294E on NM_016087.2) | Missense Mutation (SNP) | VAF 93/330 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIM2 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 116/274 reads (42%) | called by muse, mutect2, varscan2
- ZMYM3 | c.2270A>G p.Q757R | Missense Mutation (SNP) | VAF 125/249 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- ZNF142 | c.2897C>T p.S966F (on ENST00000411696 / NM_001379660.1; = p.S766F on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/426 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- ZNF385A | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 100/437 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF442 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 94/343 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF462 | c.5236C>T p.P1746S | Missense Mutation (SNP) | VAF 176/545 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF568 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 113/287 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF780B | c.1399C>T p.H467Y | Missense Mutation (SNP) | VAF 114/311 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNFX1 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSWIM2 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSWIM5 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 93/362 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AARS2 | c.1800C>T p.I600= | Silent (SNP) | VAF 204/729 reads (28%) | catalogued as COSV55114219; called by muse, mutect2, varscan2
- ABCB11 | c.3453C>T p.F1151= | Silent (SNP) | VAF 93/421 reads (22%) | catalogued as COSV55587639; called by muse, mutect2, varscan2
- ABCF1 | c.1074C>T p.P358= (on ENST00000326195 / NM_001025091.2; = p.P320= on NM_001090.3) | Silent (SNP) | VAF 145/681 reads (21%) | catalogued as COSV100400978; called by muse, mutect2, varscan2
- AC069544.2 | c.39C>T p.S13= | Silent (SNP) | VAF 42/204 reads (21%) | called by muse, mutect2, varscan2
- ACAD8 | c.1135C>T p.L379= | Silent (SNP) | VAF 94/381 reads (25%) | catalogued as COSV99844067; called by muse, mutect2, varscan2
- ACSM6 | c.816A>T p.G272= | Silent (SNP) | VAF 105/312 reads (34%) | called by muse, mutect2, varscan2
- ADAM33 | c.2223G>A p.R741= | Silent (SNP) | VAF 69/350 reads (20%) | catalogued as rs1186137657; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2643C>T p.F881= | Silent (SNP) | VAF 136/416 reads (33%) | catalogued as rs778176189, COSV65901867; called by muse, mutect2, varscan2
- ADGRF1 | c.1029G>A p.G343= | Silent (SNP) | VAF 115/585 reads (20%) | called by muse, mutect2, varscan2
- ADGRF3 | c.1191G>A p.P397= (on ENST00000311519 / NM_001145168.1; = p.P198= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 122/389 reads (31%) | catalogued as rs775063923; called by muse, mutect2, varscan2
- ADGRF5 | c.2679G>A p.S893= | Silent (SNP) | VAF 85/333 reads (26%) | catalogued as rs754033512; called by muse, mutect2, varscan2
- ADGRV1 | c.3561C>T p.I1187= | Silent (SNP) | VAF 54/376 reads (14%) | catalogued as COSV67997692; called by muse, mutect2, varscan2
- AGMAT | c.564G>A p.T188= | Silent (SNP) | VAF 137/492 reads (28%) | catalogued as rs1386126950; called by muse, mutect2, varscan2
- AKR1B1 | c.222C>T p.F74= | Silent (SNP) | VAF 169/449 reads (38%) | catalogued as COSV53648066; called by muse, mutect2, varscan2
- AL592490.1 | c.870C>T p.I290= | Silent (SNP) | VAF 137/344 reads (40%) | catalogued as COSV69426297; called by muse, mutect2, varscan2
- ALK | c.678C>T p.S226= | Silent (SNP) | VAF 54/286 reads (19%) | catalogued as COSV66572187; called by muse, mutect2
- ALS2CL | c.2442C>T p.P814= | Silent (SNP) | VAF 105/405 reads (26%) | catalogued as rs1284605701; called by muse, mutect2
- AMPH | c.363G>A p.L121= | Silent (SNP) | VAF 50/226 reads (22%) | catalogued as COSV57739420; called by muse, mutect2, varscan2
- ANKFN1 | c.3285G>A p.V1095= (on ENST00000653862; = p.V948= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 129/497 reads (26%) | called by muse, mutect2, varscan2
- ANKRD30A | c.3363G>A p.L1121= (on ENST00000611781; = p.L1065= on NM_052997.2) | Silent (SNP) | VAF 66/259 reads (25%) | catalogued as COSV64612112; called by muse, mutect2, varscan2
- ANO10 | c.762C>T p.S254= | Silent (SNP) | VAF 120/445 reads (27%) | catalogued as rs1559730126; called by muse, mutect2, varscan2
- AP3B2 | c.3246G>A p.V1082= (on ENST00000261722; = p.V1076= on NM_004644.5) | Silent (SNP) | VAF 94/307 reads (31%) | catalogued as COSV99917133; called by muse, mutect2, varscan2
- AQP5 | c.642G>A p.A214= | Silent (SNP) | VAF 74/306 reads (24%) | catalogued as rs369598571; called by muse, varscan2
- ARHGAP23 | c.954C>T p.D318= | Silent (SNP) | VAF 180/712 reads (25%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.153C>T p.T51= | Silent (SNP) | VAF 62/312 reads (20%) | catalogued as rs192254681; called by muse, varscan2
- ARMC4 | c.1368G>A p.K456= | Silent (SNP) | VAF 47/222 reads (21%) | catalogued as COSV53469509; called by muse, mutect2, varscan2
- ASTN1 | c.384C>T p.A128= | Silent (SNP) | VAF 99/456 reads (22%) | catalogued as rs1383681865; called by muse, mutect2, varscan2
- ASXL3 | c.5688G>A p.Q1896= | Silent (SNP) | VAF 79/289 reads (27%) | called by muse, mutect2, varscan2
- ATF6 | c.1884C>T p.I628= | Silent (SNP) | VAF 188/337 reads (56%) | catalogued as COSV63409828; called by muse, mutect2, varscan2
- ATP2B3 | c.1020G>A p.G340= | Silent (SNP) | VAF 204/356 reads (57%) | catalogued as COSV54855237; called by muse, mutect2, varscan2
- ATR | c.1924C>T p.L642= | Silent (SNP) | VAF 83/302 reads (27%) | called by muse, mutect2, varscan2
- ATXN2 | c.663G>A p.S221= (on ENST00000550104; = p.S61= on NM_002973.4) | Silent (SNP) | VAF 119/394 reads (30%) | called by muse, mutect2, varscan2
- BAIAP2L1 | c.429C>T p.I143= | Silent (SNP) | VAF 106/403 reads (26%) | called by muse, varscan2
- BAZ2A | c.895C>T p.L299= | Silent (SNP) | VAF 69/258 reads (27%) | catalogued as rs779279173; called by muse, mutect2, varscan2
- BMP2 | c.417C>T p.I139= | Silent (SNP) | VAF 57/283 reads (20%) | catalogued as COSV66578762; called by muse, mutect2, varscan2
- C11orf16 | c.1287G>A p.K429= | Silent (SNP) | VAF 171/495 reads (35%) | catalogued as rs1455743912; called by muse, mutect2, varscan2
- C5 | c.3999C>T p.F1333= | Silent (SNP) | VAF 70/269 reads (26%) | catalogued as COSV99798872; called by muse, mutect2, varscan2
- C8A | c.639G>A p.L213= | Silent (SNP) | VAF 52/224 reads (23%) | catalogued as COSV100776652; called by muse, mutect2, varscan2
- CACNA1S | c.342G>A p.Q114= | Silent (SNP) | VAF 201/553 reads (36%) | called by muse, mutect2, varscan2
- CALCR | c.510C>T p.F170= | Silent (SNP) | VAF 85/311 reads (27%) | catalogued as rs200267145, COSV64008363; called by muse, mutect2, varscan2
- CAPN12 | c.1074C>T p.T358= | Silent (SNP) | VAF 119/425 reads (28%) | catalogued as rs745993253; called by muse, mutect2, varscan2
- CAPN13 | c.624C>T p.S208= | Silent (SNP) | VAF 109/551 reads (20%) | called by muse, mutect2, varscan2
- CARS2 | c.691C>T p.L231= | Silent (SNP) | VAF 127/357 reads (36%) | catalogued as rs774297299; called by muse, mutect2, varscan2
- CCM2L | c.1050G>A p.R350= | Silent (SNP) | VAF 71/345 reads (21%) | called by muse, mutect2, varscan2
- CCR4 | c.924G>A p.G308= | Silent (SNP) | VAF 81/288 reads (28%) | called by muse, mutect2, varscan2
- CD101 | c.1881C>T p.V627= | Silent (SNP) | VAF 117/468 reads (25%) | catalogued as rs780946166; called by muse, mutect2, varscan2
- CD33 | c.669G>A p.T223= | Silent (SNP) | VAF 103/282 reads (37%) | catalogued as rs750832576, COSV99220855; called by muse, mutect2, varscan2
- CDH11 | c.1245C>T p.S415= | Silent (SNP) | VAF 89/245 reads (36%) | called by muse, mutect2, varscan2
- CDH20 | c.2250C>T p.F750= | Silent (SNP) | VAF 156/563 reads (28%) | catalogued as rs1271182303, COSV53015064, COSV53018004, COSV99405096; called by muse, mutect2, varscan2
- CDHR2 | c.2526G>A p.L842= | Silent (SNP) | VAF 252/596 reads (42%) | called by muse, mutect2, varscan2
414 further variants in this file (0 protein-altering or splice-affecting, 360 silent, 54 other) are not listed here.
